Gene-level copy-number profile of tumor specimen TCGA-B6-A0RS-01A from TCGA case TCGA-B6-A0RS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 38.7 years (14,134 days).
Specimen TCGA-B6-A0RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e191f444-0987-42d9-baed-ceb74591810f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0RS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48f71daa-5e12-422d-bb39-2b2a1d150ef3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 779; copy number 2: 11,479; copy number 3: 11,059; copy number 4: 23,396; copy number 5: 7,281; copy number 6: 2,941; copy number 7: 2,498; copy number 8: 60; copy number 9: 227; copy number 12: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0RS-01A-11D-A087-01): tumor purity 0.51, ploidy 3.54, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,026,456–190,092,279, 83 genes (broad region; genes not listed).
- chr6:167,767,083–168,101,511, 10 genes: AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 231 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,505,508–172,604,006, 4 genes, copy number 12: TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr9:14,475–17,797,124, 227 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 779. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
